Surgical pathology report (de-identified scan), TCGA case TCGA-FP-8209, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-8209-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

Stomach, distal gastrectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma, diffuse type.
2. Location of tumor: Prepyloric.
3. Tumor size: 3 x 1 x 1.5 cm.
4. Tumor configuration: Exophytic and infiltrative.
5. Histologic grade: Poorly differentiated.
6. Extent of invasion: Malignancy invades deeply into but not through the muscularis propria.
7. Lymphovascular space invasion: Not identified.
8. Perineural invasion: Not identified.

T2a

Surgical Margin Status:

1. Proximal margin: Widely free of involvement.
2. Distal margin (duodenum): Free of involvement (2.5 cm).
3. Radial margin: Free of involvement, 0.5 cm.

No

Lymph Node Status:

1. Total number of lymph nodes examined: 5.
2. Total number of lymph nodes containing metastatic carcinoma: 0.
3. Negativity confirmed with appropriately controlled pancytokeratin immunostain.

Other:

1. Findings correspond to those in a prior gastric biopsy
2. Sections have also been reviewed by Dr. _____ who is in agreement.

Electronic Signature: _____

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Cancer of distal stomach on endoscopy

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Distal stomach

SPECIMEN DATA

[page 2 of 2]
GROSS DESCRIPTION:

The specimen is received in one container labeled [REDACTED] and distal stomach and consists of an unoriented portion of stomach measuring 14.0 x 6.0 x 3.5 cm. The surface is gray-tan to brown-tan and slightly roughened. There is one opened margin and one stapled margin. On opening the stomach the mucosal surface is light tan and reveals normal rugate folds. There is a nodular mass identified measuring 3.0 x 1.0 cm with area of hemorrhage that is 2.6 cm from the stapled margin and 12.0 cm from the opened margin. On sectioning the wall is thickened and fibrotic. There is a portion of omentum attached measuring 6.0 x 1.0 x 0.5 cm. On sectioning there are five lymph nodes measuring from 0.2 to 0.4 cm. Representative sections were taken for genomic studies and placed in orange cassettes A-D. Also received with the specimen are three cassettes, one yellow, one green and one blue labeled [REDACTED]. Representative sections are submitted in cassettes labeled as follows: opened margin--1; stapled margin--2; sections from mass--3 to 6; lymph nodes--7.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file f41c6eb3-3fbb-47d9-b5e2-a3887ebcaafd (TCGA-FP-8209.E54F7F39-EA04-4149-B319-93A60B91CF86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).